Clinical report (de-identified scan), EXCEPTIONAL_RESPONDERS case ER-ADXD, project EXCEPTIONAL_RESPONDERS-ER (Exceptional Responders), specimen ER-ADXD-TTP1-A (Primary Tumor).

[page 1 of 15]
Anatomic Pathology Results Posted by Result Date (Reverse Chronological Order):

Please review all results carefully. This report does not flag clinically significant results.

Result Date/Time: [REDACTED] +294

FINAL REPORT

SURG PATH FINAL REPORT

SURGICAL PATHOLOGY

Collected: [REDACTED] +294
Accession: [REDACTED]
Physician: [REDACTED]

PROCEDURE

Closure loop ileostomy.

HISTORY

Status post low anterior resection for rectal cancer.

GROSS

"Ileostomy." A 8.5 x 2.5 cm segment of small bowel, partially covered by skin, 0.4 cm thick along one margin. The mucosa is unremarkable. A separate unremarkable 1.1 x 1.2 cm fragment of mucosa is received. Sampled - 2 cassettes.

DIAGNOSIS

ILEOSTOMY: FOCALLY ACTIVE CHRONIC INFLAMMATION.

COMMENT

There is no epithelial dysplasia or neoplasm.

FINAL REPORT

SURG PATH FINAL REPORT

SURGICAL PATHOLOGY

Collected: [REDACTED] +16
Accession: [REDACTED]
Physician: [REDACTED]

PROCEDURE

Lower anterior resection, ileostomy.

HISTORY

Biopsy proven rectal cancer.

GROSS

A. "Mesenteric nodule." A 0.9 cm aggregate of tumor fragments. All processed - 1 cassette.

B. "Rectum, sigmoid." A 26.5 x 3.0 cm segment of large bowel to include rectum. 2.5 cm from the distal margin of resection, below the peritoneal reflection and extending approximately 6.5 cm above

[page 2 of 15]
[REDACTED]

the peritoneal reflection, there is a circumferential obstructing 7.5 x 5.5 x 2.1 cm mass. There is serosal involvement. Multiple 0.2 up to 0.7 cm tumor nodules stud the perirectal fat and serosa. This tumor extends into the adjacent perirectal fat which contains multiple lymph nodes involved by tumor. Tumor is identified less than 0.3 cm from the closest circumferential radial margin of resection. The mesorectal envelope is complete. Multiple lymph nodes are identified many of which are involved by tumor.

B1. Tumor nodules involving serosa and perirectal fat.

Sampled - 1 cassette.

B2-3. Tumor. Sampled - 2 cassettes.

B4. Random mucosa. Sampled - 1 cassette.

B5-13. Lymph nodes. All processed -9 cassettes.

DIAGNOSIS

RECTUM: ADENOCARCINOMA WITH LYMPH NODAL METASTASES.

Specimen: sigmoid colon, rectum

Procedure: rectosigmoid colon (low anterior resection)

Tumor site: rectum

AJCC/UICC Stage: IV

Modified Astler-Coller (MACS): D

TNM-Stage: pT3 pN2b pM1

Tumor size: 7.5 cm

Histologic type: adenocarcinoma, NOS

Histologic grade: low grade

Proximal margin: uninvolved

Distal margin: uninvolved

Circumferential (radial) margin: uninvolved by invasive carcinoma

Distance of invasive carcinoma from closest margin: 0.3 cm

(circumferential

margin)

Extent of microscopic invasion: through muscularis propria into non-peritonealized perirectal soft tissue

Perforation: N/A

Contiguous organs/structures: not involved

Venous invasion: absent

Lymphatic invasion: present; extramural

Perineural invasion: present

Dirty necrosis: present

Lymphocytic response: marked (≥ 3 lymphs/hpf or crohn's-like)

Tumor margin: pushing

Tumor deposits within fat: present, at least 8 deposits

Lymph nodes (pericolic): 14 of 23 contain metastases

Number of micrometastases (0.2-2 mm): 0

MESENTERY: METASTATIC RECTAL ADENOCARCINOMA.

[REDACTED]

Result Date/Time:

+16

FINAL REPORT

SP 1ST ADDENDUM REPORT

SURGICAL PATHOLOGY

Collected:

Accession:

Physician:

+16

[page 3 of 15]
ADDENDUM REPORT

KRAS MUTATION ANALYSIS RESULTS: Positive for a p.G12V (c.35G>T) mutation in codon 12 of the KRAS gene.

INTERPRETATION:

Mutations in the KRAS gene are reported to correlate with resistance to anti-EGFR monoclonal antibody therapies in patients with colorectal cancer.

KRAS mutations occur in 30-50 of colorectal adenocarcinomas.

Result Date/Time: +16

FINAL REPORT

SP 2ND ADDENDUM REPORT

SURGICAL PATHOLOGY

Collected: +16
Accession:
Physician:

ADDITIONAL ADDENDUM REPORT

Immunoperoxidase stains were performed at determine the presence or absence of protein expression for MLH1, MSH2, MSH6, and PMS2. Lymphocytes and normal epithelium exhibit strong nuclear staining and serve as positive internal controls for staining of these four proteins. In addition, this case was submitted to for formal microsatellite instability studies by PCR.

Immunoperoxidase stains reveal normal expression of MLH1, MSH2, MSH6, and PMS2. Microsatellite instability studies reveal instability in 0 of 5 informative markers, classifying this tumor as MSS/MSI-L. The results of these studies indicate a decreased likelihood that this individual has hereditary nonpolyposis colorectal cancer (HNPCC)/Lynch Syndrome, but it does not completely exclude that possibility. This individual's tumor may be due to an inherited defect in another gene not involved in DNA mismatch repair, as a significant portion of clinically defined HNPCC cases do not have defective DNA mismatch repair as an underlying genetic basis of their disease. In addition, the possibility that this individual or the family has HNPCC is also not excluded, because this tumor could represent a sporadic occurrence. If there is a strong personal or familial history of HNPCC related cancers, additional testing on a different tumor from this individual or another family member may be helpful. A genetic consultation may be of benefit.

Result Date/Time: +0

FINAL REPORT

SURG PATH FINAL REPORT

SURGICAL PATHOLOGY

[page 4 of 15]
Collected: [REDACTED] +0
Accession: [REDACTED]
Physician: [REDACTED]

PROCEDURE

Colonoscopy with biopsy.

HISTORY

Hematochezia, constipation. Screening colonoscopy reveals a circumferential partially obstructing rectal mass from 8-20 cm, barely palpable on rectal exam and patchy mild inflammation in the ascending colon.

GROSS

- A. "Ascending." Four bits up to 0.1 cm. All processed - 1 cassette.
- B. "Rectal mass biopsies." Multiple bits up to 0.2 cm. All processed - 1 cassette.

DIAGNOSIS

COLON (ASCENDING): PATCHY ACUTE SURFACE MUCOSAL INJURY.

RECTUM: INVASIVE MODERATELY-DIFFERENTIATED ADENOCARCINOMA.

COMMENT

There is a patchy surface injury in the ascending colon biopsies with focal neutrophilic inflammation involving the surface epithelium and lamina propria. These changes are non-specific and may be seen in a self-limited resolving infectious colitis, drug/toxin effect or preparatory effect.

Result Date/Time: [REDACTED]

+0

FINAL REPORT

SP 1ST ADDENDUM REPORT

SURGICAL PATHOLOGY

Collected: [REDACTED] +0
Accession: [REDACTED]
Physician: [REDACTED]

ADDENDUM REPORT

EGFR FISH analysis reveals a low gene copy number.

Colorectal cancer (CRC) with high EGFR gene copy number have an increased likelihood of responding to Cetuximab therapy and show a significant relationship to progression free survival as compared with CRC low EGFR gene copy number. This FISH test uses EGFR-CEP Dual Color DNA Probe ([REDACTED]).

This test was performed and interpreted by [REDACTED]
EGFR mutation analysis by sequence technique is a more sensitive test.

[page 5 of 15]
* Final Report *

Reason For Exam
S/P SURGERY F/U

REPORT

NUCLEAR MEDICINE PET/CT LIMITED SUBSEQUENT COLORECTAL CANCER:

CLINICAL HISTORY: Rectal cancer with resection. Initial staging.

After a suitable fast, the patient was injected with 14.2 mCi of F-18-fluorodeoxyglucose (FDG) intravenously, followed by whole body images from the base of the skull to the proximal thigh on a dedicated PET/CT system at 64 minutes post-tracer injection. The data volume is reformatted into transverse, coronal and sagittal planes, as well as a three-dimensional volume-rendered (MIP) display. Blood glucose was 08 mg/dl. CT imaging was performed with oral contrast.

COMPARISON: Abdomen and pelvis CT +11

FINDINGS:

NECK: No concerning FDG accumulation.

CHEST: Right inferolateral hilar lymph node/nodule on image 51 measures approximately 1.4 cm with FDG of 5.8. Compatible with metastatic disease.

Right lower lobe faintly nodular focus on image 54 spanning 0.6 to 1.0 cm has FDG accumulation to 1.6. It is unclear if this will prove to a developing metastatic focus, though such is a consideration.

ABDOMEN: Multifocal FDG accumulation in the right lobe of the liver compatible with metastatic disease. Some of this is parenchymal and some of this is along portal triad, intrahepatic. Several sample measurements will be provided. See, for example, a dominant right lobe lesion on image 70 measuring 4.1 x 4.5 cm with FDG to approximately 10.3. See also along right portal triad/vein, perhaps a tumor thrombus, on image 71 spanning approximately 2.2 x 3.4 cm in its most intense central portion with intensity to 7.6. Wispy distal extension extends therefrom.

Small amounts of ventral midline abdominal activity is probably post-surgical.

[page 6 of 15]
PELVIS: Sigmoidectomy with anastomosis. Ostomy in the right lower quadrant is present.

Presumably diverting, though an additional suture line is present in the region involving small bowel such that it is hard to exclude it from being an end ileostomy.

Infiltrative stranding surrounding rectosigmoid surgical bed and extending into the presacral space. Much of this is low level suggesting inflammatory change. There is a nodular focus in the right pelvis on image 121 spanning approximately 1.6 x 1.5 cm with intensity to 4.8 compatible with neoplastic lymph node or nodule. Probably stable compared to prior accounting for measurement error limitation.

IMPRESSION:

1. Multifocal metastatic disease.
2. There is metastatic disease in the right lobe of the liver, involving both the parenchyma and the portal triad.
3. Postoperative changes in the pelvis. Some intermediate level FDG accumulation scattered in the surgical bed is present and could simply be post-surgical inflammatory. It is hard to exclude residual neoplasm within these intermediate to low level foci. There is, however, a more intense focal nodular abnormality deep in the left pelvis compatible with residual neoplastic lymph node.
4. Neoplastic lymph node/nodule in the right peripheral hilum/peri-hilum. There is a focus of slight nodularity with low to intermediate FDG accumulation in the nearby right lower lobe; though strictly speaking this peripheral parenchymal focus is indeterminate, the possibility that it is metastatic disease is a prime consideration.

Signature Line

Type:
Date:

NM PET CT LTD Subsq Colorectal

+48

[page 7 of 15]
Status:

Title:

By:

Verified By:

Encounter info:

Auth (Verified)

NM PET CT LTD Subsq Colorectal

+48

[page 8 of 15]
*** Final Report ***

Reason For Exam

COLON CANCER/ SUBSEQUENT RESTAGING

REPORT

PET CT LIMITED SUBSEQUENT COLORECTAL:

DATE OF EXAM: [REDACTED] +244

COMPARISON: [REDACTED] +132

CLINICAL HISTORY: Colon cancer subsequent restaging. Additional history from patient: ~+0
Colon cancer [REDACTED] Surgery and chemotherapy.

After a suitable fast, the patient was injected with 19.2 mCi of F-18-fluorodeoxyglucose (FDG) intravenously, followed by whole body images from the base of the skull to the proximal thigh on a dedicated PET/CT system at 72 minutes post-tracer injection. The data volume is reformatted into transverse, coronal and sagittal planes, as well as a three-dimensional volume-rendered (MIP) display. Blood glucose was 90 mg/dl. CT imaging was performed with oral contrast.

FINDINGS:

NECK: No concerning FDG accumulation.

CHEST: A couple of foci borderline prominent FDG accumulation are present in the hila bilaterally and adjacent to the aortic root. These lie within subcentimeter lymph nodes. There are not necessarily enough to necessarily confirm site disease at the present time but warrant attention on followup.

ABDOMEN: No concerning FDG accumulation in the liver. Hypodense focus in the right lobe on image 68 measures 3.1 x 3.3 which is stable within measurement error limitation compared to [REDACTED] +132

Spleen activity borderline prominent; perhaps it is related to the same process as the bone marrow.

PELVIS: No FDG accumulation concerning for neoplasm. Right lower quadrant ostomy, assuming made a diverting ileostomy. Rectosigmoid anastomotic line.

[page 9 of 15]
OTHER: Wide spread marrow FDG accumulation may be a rebound hematopoietic effect.

IMPRESSION:

1. No definite FDG avid neoplasm. A few subcentimeter lymph nodes in the mediastinum and hila are borderline prominent in FDG accumulation. Tried to fully exclude neoplastic involvement there within though it is not specific or particularly convincing. The most suspicious foci is adjacent to the ascending aorta. It is slightly more conspicuous than prior though it remains unclear if it is truly concerning abnormal. Attention on followup is warranted.
2. Wide spread marrow activity is developed compatible with a hematopoietic rebound effect.

Type: NM PET CT LTD Subsseq Colorectal ()
Date: +244
Status: Auth (Verified)
Title: NM PET CT LTD Subsseq Colorectal ()
By:
Verified By:
Encounter info:
+244

[page 10 of 15]
*** Final Report ***

Reason For Exam

RESTAGING HX METASTATIC COLON CA, PAIN IN LT SI AREA

REPORT

CT Abd and Pelvis w Contrast, CT Chest w Contrast

COMPLETED DATE: [REDACTED] +1695

REASON FOR EXAM: RESTAGING HX METASTATIC COLON CA, PAIN IN LT SI AREA

ADDITIONAL HISTORY PROVIDED BY CLINICAL TEAM: None Provided

HISTORY OBTAINED BY THE TECHNOLOGIST: Restaging cancer metastatic colon cancer. pain left SI area.

SMOKING HISTORY: Do you or have you ever smoked? Quit. Packs per day? 1
Years smoked? 23 Year quit? [REDACTED] ~-1213

PROTOCOL: Routine chest, abdomen and pelvis CT performed. High density oral contrast was used. No additional scan parameters were utilized

IV CONTRAST: 100 mL Isovue 370

COMPARISON: [REDACTED] +1513

FINDINGS:

The lungs are clear. No pleural effusion.

No mediastinal or hilar lymphadenopathy.

Mild atherosclerotic changes aorta with moderate coronary artery calcification. Heart size normal. Pericardium normal.

No focal mass in the liver or spleen.

Gallstones within gallbladder.

The pancreas, kidneys, and adrenal glands are normal.

No lymphadenopathy or ascites in the abdomen/pelvis.

Small bilateral inguinal hernias containing fat.

Mild diverticulosis sigmoid colon without evidence for diverticulitis.

Small ventral hernia containing small portion of bowel and fat. No obstruction.

No suspicious osseous lesion.

No bowel obstruction. Appendix normal.

[page 11 of 15]
IMPRESSION: No evidence to suggest recurrent/metastatic disease.

Signature Line

***** FINAL REPORT

Type: CT Abd and Pelvis w Contrast
Date: [Redacted] +244
Status: Auth (Verified)
Title: CT Abd and Pelvis w Contrast
By: [Redacted]
Verified By: [Redacted]
Encounter info: [Redacted]

+1695

[page 12 of 15]
[REDACTED]

Patient Name: [REDACTED]

Admit Date: +1513

Date of Birth: [REDACTED]

Patient Status:

[REDACTED]
Outpatient

Exam Date and Time: +1513

Test / Status:

CT Abd and Pelvis w Contrast / Final

Reason for Exam:

RECTAL CA RESTAGING

Ordering:

Provider:

Result

CT Abd and Pelvis w Contrast, CT Chest w Contrast

COMPLETED DATE: [REDACTED] +1513

CLINICAL HISTORY: RECTAL CA RESTAGING

ADDITIONAL COMMENTS: Surgery and chemotherapy [REDACTED]

COMPARISON: CT scan [REDACTED] +1320

PROCEDURE: Routine chest, abdomen and pelvis CT after the administration of oral contrast and 100 mLs of nonionic intravenous contrast

FINDINGS:

CHEST CT:

Lungs remain clear with no nodules nor pleural effusions. No thoracic adenopathy of significance. No significant osseous abnormality coronary artery atherosclerotic calcifications present as a marker for coronary artery disease.

ABDOMEN PELVIC CT:

+1152

Vague hypodense appearance right lobe liver unchanged back to [REDACTED] likely due to portal vein occlusion in this area. No new liver lesion. Spleen, gallbladder, adrenals, kidneys, and pancreas unremarkable except for a few small calcified gallstones and tiny renal cysts too small to characterize.

No adenopathy of significance nor abnormal fluid collection. No obvious enteric abnormality. Small fat-containing supraumbilicus and umbilicus hernia is with a tiny infraumbilical fat-containing ventral midline hernia. These do not appear greatly changed from prior. No significant new osseous abnormality.

IMPRESSION:

1. No CT evidence of tumor recurrence/metastasis
- [REDACTED]
- [REDACTED]

[page 13 of 15]
[REDACTED]

Patient Name:

Admit Date: +1513 [REDACTED]

Patient Status:

* * Outpatient

Exam Date and Time: +1513 [REDACTED]

Test / Status: CT Abd and Pelvis w Contrast / Final

Reason for Exam: RECTAL CA RESTAGING

Ordering:

Provider:

Result

[REDACTED] +1513

[page 14 of 15]
[REDACTED]
Admit Date:

+1513

Date of Birth:

Exam Date and Time:

+1513

Patient Status:

[REDACTED]
Outpatient

Test / Status:

CT Abd and Pelvis w Contrast / Final

Reason for Exam:

RECTAL CANCER

Ordering:

Provider:

Result

CT Chest w Contrast, CT Abd and Pelvis w Contrast

COMPLETED DATE: [REDACTED] +1513

REASON FOR EXAM: Rectal cancer, restaging.

[REDACTED]
HISTORY OBTAINED BY THE TECHNOLOGIST: Follow up of rectal cancer with lung and liver metastasis. No new symptoms.

SMOKING HISTORY: Do you or have you ever smoked? Quit. Packs per day? 1 Years smoked? 30 Year quit? [REDACTED]

PROTOCOL: Routine chest, abdomen and pelvis CT performed. Routine chest, abdomen and pelvis CT performed. No additional scan parameters were utilized

IV CONTRAST: 100 mg/ml of Isovue 370 (accession [REDACTED]) Done with chest CT (accession [REDACTED])

COMPARISON: [REDACTED] +1695

FINDINGS:

CHEST:

LUNGS: Clear. Central airways patent.

AXILLA, MEDIASTINUM, AND HILA: No suspicious axillary, mediastinal, or hilar lymphadenopathy.

HEART AND GREAT VESSELS: No pericardial effusion. Mild to moderate coronary artery calcific calcifications.

PLEURAL SPACES: No pneumothorax or pleural effusion.

ABDOMEN AND PELVIS:

LIVER: Normal.

GALLBLADDER: Cholelithiasis.

PANCREAS: Normal.

SPLEEN: Normal.

ADRENALS: No mass or nodule.

KIDNEYS: Mild cortical scarring along the anterior midpole of the left kidney.

LYMPH NODES: No suspicious intra-abdominal lymphadenopathy. No suspicious inguinal or [REDACTED]

[page 15 of 15]
[REDACTED]

Patient Name:

Admit Date:

Exam Date and Time:

Test / Status:

Reason for Exam:

Ordering:

Provider:

+2066

+2066

Date of Birth:

Patient Status:

Outpatient

CT Abd and Pelvis w Contrast / Final

RECTAL CANCER

Result

LYMPH NODES: No suspicious intra-abdominal lymphadenopathy. No suspicious inguinal or pelvic lymphadenopathy.

BOWEL: Normal caliber. No obstructive findings. Appendix is visualized and is normal.

Anastomosis sutures at the rectosigmoid junction.

ABDOMINAL AORTA: Fusiform dilatation of the intrarenal abdominal aorta which measures up to 2.9 x 2.8 cm in maximal caliber.

PELVIC ORGANS: Normal.

IMPRESSION:

1. No evidence of residual, recurrent, or metastatic disease in the chest, abdomen, or pelvis.
- [REDACTED]

Source: NCI Genomic Data Commons file bb7204dd-1905-41df-91a1-491aa9e5677a (ER0384 ER-ADXD Clinical Report_Redacted_Sanitized.pdf), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).